Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A1E4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A1E4-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Adenocarcinoma, endometrioid, NOS 8380/3
Site Code: Endometrium C54.

TSS Name/##:

1/15

Specimens Submitted:

- 1: SP: Uterus, cervix, ovaries and fallopian tubes; total abdominal hysterectomy and bilateral salpingo-oophorectomy
- 2: SP: Sentinel lymph node, obturator, left
- 3: SP: Sentinel lymph node, obturator, right

DIAGNOSIS:

1. SP: Uterus, cervix, ovaries and fallopian tubes; total abdominal hysterectomy and bilateral salpingo-oophorectomy:

Tumor Type:

Adenocarcinoma, endometrioid type

Architectural Grade (For Endometrioid Types only):

II (6-50% solid growth)

Nuclear Grade (For Endometrioid Types only):

Grade 2

FIGO Grade (For Endometrioid Types only):

Grade 2

Myometrial Invasion:

(>50%)

Measures 15mm in maximum depth

Myometrium thickness measures 26mm in the area of maximal tumor

invasion

Endocervical Invasion:

Not identified

Lymphovascular invasion:

Identified

Endometrium:

Exhibits complex hyperplasia with atypia

Myometrium:

Exhibits adenomyosis

Adnexa:

Unremarkable

2. SP: Sentinel lymph node, obturator, left:
Lymph Node Dissection:

** Continued on next page **

[page 2 of 2]
TSS Name/##:

----- Page 2 of 4
Benign lymph nodes
Number of lymph nodes examined: 1
with endosalpingiosis

NOTE: IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATIN AE1/3 ARE NEGATIVE FOR
METASTATIC CARCINOMA, BUT HIGHLIGHT ENDOSALPINGIOSIS.

3. SP: Sentinel lymph node, obturator, right:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 2

NOTE: IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATIN AE1/3 ARE NEGATIVE FOR
METASTATIC CARCINOMA.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Source: NCI Genomic Data Commons file 7645c101-331c-4b9f-820d-d04b9552ecd5 (TCGA-AP-A1E4.1E33ABA3-0B55-4021-A370-DB8E2CA4C022.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).